Gene-level copy-number profile of tumor specimen TCGA-XF-A8HE-01A from TCGA case TCGA-XF-A8HE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 47.1 years (17,212 days).
Specimen TCGA-XF-A8HE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.15e7107b-28ab-4e9d-8cde-39369c64526e.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,699 have no estimate.
https://portal.gdc.cancer.gov/files/25011410-9ea6-4d27-aad0-601470dbf6e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 3,767; copy number 2: 51,137; copy number 4: 1,952; copy number 5: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HE-01A-11D-A363-01): tumor purity 0.37, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,699,314–24,592,104, 34 genes: RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr10:87,591,607–88,700,401, 21 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1.
- chr10:88,727,485–88,728,914, 1 gene: KRT8P38.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:109,334,713–109,467,952, 3 genes, copy number 5 (within-gene range 2–5): PJA2, AC010625.1, AC091917.3.
- chr12:7,812,512–7,972,759, 8 genes, copy number 5 (within-gene range 2–5): SLC2A14, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6.
- chr17:36,116,177–36,177,510, 1 gene, copy number 5: AC243829.2.

Autosomal genes at a single copy (total copy number 1): 3,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
